HCMI case HCM-BROD-0677-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fb3cac25-28e3-4677-868a-0e4ba6703dee

Demographics
Sex at birth: female; Race: white; Year of birth: 1953; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 55.1 years (20,120 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: T3b; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,464 days (4.0 years); Days to treatment end: 1,464 days (4.0 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.8; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 59.0 years (21,552 days); Days to diagnosis: 1,432 days (3.9 years); Satellite nodule present: Absent.
   Pathology details: Breslow thickness category: >2.0-4.0 mm; Lymph nodes positive: 1; Lymph nodes tested: 14; Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (2 entries)
- Days to follow up: 4,536 days (12.4 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 4,074.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600E.
- KIT mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 97 kg; Height: 165 cm; BMI: 36.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Melanoma.

Biospecimens (2 samples)
- Sample HCM-BROD-0677-C43-12A: Sample type: Saliva; Tissue type: Normal; Specimen type: Saliva; Preservation method: Frozen.
- Sample HCM-BROD-0677-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 3.
